Surgical pathology report (de-identified scan), TCGA case TCGA-77-7141, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-7141-01A (Primary Tumor).

[page 1 of 2]
HISTORY

MACROSCOPIC

Four specimens received:

1: The specimen is labelled "left upper lobe" and consists of a lobectomy specimen measuring 130 x 80 x 35 mm. The bronchial portion of the specimen measures approximately 30 mm in length and has a bifurcation adjacent to the resection margin with two adjacent lumens measuring approximately 13 mm in diameter, one of which is plugged by cream to pink tumour. No palpable mass is present within the lobectomy specimen. The pleural surface demonstrates mild anthracotic pigmentation. Several small peribronchial lymph nodes are present. Tumour is seen plugging the two described bronchi and, on sectioning, is seen to involve several adjacent second order branches. The tumour appears clear of the peribronchial soft tissue resection margins and does not appear to be invading lung parenchyma macroscopically. The tumour extends approximately 45 mm along the first and second order bronchi. [TS of bronchial resection margin containing tumour plug and peribronchial lymph nodes, 1A; TS of bronchial resection margin not containing tumour, inked side down, and peribronchial nodes, 1B; TS of first order bronchi containing tumour, 1C-D; TS of intrapulmonary bronchi, 1E; section of normal lung, 1F; sections of tumour and normal lung taken for lung tumour research project].

2: The specimen is labelled "lingular margin left lobe" and consists of an opened strip of bronchial wall measuring approximately 32 x 4 x 2 mm. The mucosal surface appears normal. The specimen is not oriented in any way. [BIT on edge, 2A].

3: The specimen is labelled "hilar lymph nodes" and consists of five small pieces of fatty tissue each of which appears to contain a small lymph node, the largest of which measures approximately 6 mm in maximum extent. [All wrapped and BIT, 3A].

4: The specimen is labelled "mediastinal lymph nodes" and consists of fatty tissue containing two identifiable lymph nodes measuring 3 mm and 11 mm in maximum extent respectively. [Both BIT, 4A]

MICROSCOPIC

1: Sections show a largely exophytic, moderately differentiated squamous cell carcinoma which fills bronchial lumens and invades down to and between bronchial cartilages to abut the external bronchial soft tissue resection margin in areas. Definite transection of tumour nests at these margins is not identified. Tumour involves one of the bronchial end resection margins. There is no invasion of lung parenchyma. No lymphatic or vascular invasion is found, but focal perineural infiltration is noted. None of the peribronchial lymph nodes contains metastatic carcinoma, although tumour abuts the capsule of one node. The distal lung parenchyma is atelectatic and contains a few scattered fibromuscular scars.

2: Sections show bronchial wall lined by partly denuded respiratory epithelium. There is focal thin squamous metaplasia but no evidence of dysplasia or malignancy.

3 & 4: Sections show anthracotic lymph nodes in which there is no evidence of metastatic carcinoma.

SUMMARY

Left upper lobectomy and lymph node sampling:

Largely endobronchial, moderately differentiated squamous cell carcinoma, 45 mm in greatest dimension.

Perineural invasion present.

No vascular or lymphatic invasion present.

No lymph node metastases.

Pathological stage T2 N0.

[page 2 of 2]
T-28000 M-80703 P1-03000

cc: Lung Cancer Registry

Source: NCI Genomic Data Commons file 2d8bf0c2-edf1-4dd3-8f00-c723be9babb7 (TCGA-77-7141.C8D8D890-F2A1-4B25-BA59-BCF0F69553B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).